Somatic mutation profile of tumor specimen TCGA-56-8504-01A (aliquot TCGA-56-8504-01A-11D-2395-08) from TCGA case TCGA-56-8504, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 74.5 years (27,210 days).
Specimen TCGA-56-8504-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) afa5a654-93d8-46d0-98cd-71eafa8b27c3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-56-8504-10A (Blood Derived Normal), aliquot TCGA-56-8504-10A-01D-2395-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/175a2906-d7fb-4821-860e-6fbe02151b97

The open-access MAF lists 253 somatic variants for this specimen: 195 protein-altering or splice-affecting, 55 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 170, Silent 55, Nonsense Mutation 10, Frame Shift Del 6, Splice Site 4, Frame Shift Ins 3, In Frame Del 1, 3'UTR 1, Splice Region 1, 5'UTR 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTEN | c.144C>A p.N48K | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs762518389, CM033665, COSV64308258; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.476C>T p.A159V | Missense Mutation (SNP) | VAF 52/90 reads (58%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.772); catalogued as rs1555526131, COSV52674926, COSV52693942, COSV52759722; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AC004922.1 | c.1358C>A p.S453Y | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99402765; called by muse, mutect2, varscan2
- ACAN | c.2740G>T p.V914L | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT tolerated (0.62); PolyPhen benign (0.062); catalogued as COSV100716731; called by muse, mutect2, varscan2
- ACSM2B | c.1097C>T p.T366M | Missense Mutation (SNP) | VAF 52/152 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.839); catalogued as rs372593813; called by muse, mutect2, varscan2
- ACSS3 | c.1687G>T p.G563C | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV99698093; called by muse, mutect2
- ALLC | c.558C>A p.D186E | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.625); catalogued as COSV99377322; called by muse, mutect2, varscan2
- ANGPTL2 | c.469del p.Q157Sfs*7 | Frame Shift Del (DEL) | VAF 16/68 reads (24%) | catalogued as COSV99402783; called by mutect2, pindel, varscan2
- AP002512.3 | c.395T>A p.V132E | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.726); catalogued as COSV99687666; called by muse, mutect2, varscan2
- AP3D1 | c.2095G>A p.V699M | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.487); catalogued as rs201591947; called by muse, mutect2, varscan2
- ARRB2 | c.1060C>T p.P354S | Missense Mutation (SNP) | VAF 108/178 reads (61%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV99346900; called by muse, mutect2, varscan2
- ASIC2 | c.186G>C p.E62D | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT tolerated (0.83); PolyPhen benign (0.003); catalogued as COSV100725307; called by muse, mutect2, varscan2
- ATP10A | c.1022T>A p.L341* | Nonsense Mutation (SNP) | VAF 20/69 reads (29%) | catalogued as COSV100790727; called by muse, mutect2, varscan2
- ATP13A5 | c.64G>T p.E22* | Nonsense Mutation (SNP) | VAF 23/242 reads (10%) | catalogued as COSV100664596; called by muse, mutect2
- ATP4A | c.463G>T p.G155C | Missense Mutation (SNP) | VAF 9/89 reads (10%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV99381968; called by muse, mutect2, varscan2
- BCAS3 | c.1472G>T p.G491V | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT tolerated (0.48); PolyPhen probably damaging (0.994); catalogued as COSV101174823; called by muse, mutect2, varscan2
- BDH1 | c.925A>T p.T309S | Missense Mutation (SNP) | VAF 55/219 reads (25%) | SIFT tolerated (0.62); PolyPhen benign (0.001); catalogued as COSV100827005; called by muse, mutect2, varscan2
- BMP4 | c.496G>T p.D166Y | Missense Mutation (SNP) | VAF 38/64 reads (59%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.555); catalogued as COSV99816696; called by muse, mutect2, varscan2
- C22orf15 | c.303T>A p.D101E | Missense Mutation (SNP) | VAF 42/94 reads (45%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.84); catalogued as COSV100533518; called by muse, mutect2, varscan2
- CAND2 | c.1922C>G p.P641R (on ENST00000456430 / NM_001162499.2; = p.P548R on NM_012298.3) | Missense Mutation (SNP) | VAF 47/114 reads (41%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.706); catalogued as COSV99928400; called by muse, mutect2, varscan2
- CASD1 | c.1237G>T p.G413* | Nonsense Mutation (SNP) | VAF 7/21 reads (33%) | catalogued as COSV99802098; called by muse, mutect2, varscan2
- CCDC33 | c.2152C>T p.H718Y | Missense Mutation (SNP) | VAF 22/86 reads (26%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.187); catalogued as COSV99165861; called by muse, mutect2, varscan2
- CD163 | c.757G>A p.D253N | Missense Mutation (SNP) | VAF 38/174 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63130360; called by muse, mutect2, varscan2
- CD84 | c.259G>T p.A87S | Missense Mutation (SNP) | VAF 38/166 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.058); catalogued as COSV100245746; called by muse, mutect2, varscan2
- CDH10 | c.2128G>T p.V710F | Missense Mutation (SNP) | VAF 25/97 reads (26%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.685); catalogued as COSV100049621, COSV52598944, COSV52600093; called by muse, mutect2, varscan2
- CDH13 | c.1243A>C p.T415P | Missense Mutation (SNP) | VAF 46/118 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV99221170; called by muse, mutect2, varscan2
- CDH6 | c.2323A>G p.K775E | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.202); catalogued as rs1322888781, COSV99417718; called by muse, mutect2, varscan2
- CDK12 | c.4370T>G p.L1457R (on ENST00000447079 / NM_016507.4; = p.L1448R on NM_015083.3) | Missense Mutation (SNP) | VAF 34/112 reads (30%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.178); catalogued as COSV101420248; called by muse, mutect2, varscan2
- CENPK | c.242C>T p.T81I | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99669325; called by muse, mutect2, varscan2
- CIDEC | c.617C>A p.S206Y | Missense Mutation (SNP) | VAF 25/91 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100396491, COSV61062198; called by muse, mutect2, varscan2
- CLDN25 | c.416G>T p.W139L | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.1); catalogued as COSV101493574; called by muse, mutect2, varscan2
- CNGA4 | c.1180G>T p.A394S | Missense Mutation (SNP) | VAF 58/225 reads (26%) | SIFT tolerated (0.16); PolyPhen benign (0.348); catalogued as COSV101171708; called by muse, mutect2, varscan2
- CNTN4 | c.499G>T p.D167Y | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100638651; called by muse, mutect2, varscan2
- CNTN6 | c.1708C>A p.H570N | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs769806833, COSV100609714; called by muse, mutect2, varscan2
- CNTNAP2 | c.1843G>C p.D615H | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100661638; called by muse, mutect2, varscan2
- COL22A1 | c.4837T>C p.F1613L | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.23); catalogued as COSV100275575; called by muse, mutect2, varscan2
- COPS2 | c.190A>T p.K64* | Nonsense Mutation (SNP) | VAF 4/22 reads (18%) | catalogued as COSV100157063; called by muse, varscan2
- CSGALNACT2 | c.1079A>C p.E360A | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.672); catalogued as COSV100989713; called by muse, mutect2, varscan2
- CSMD3 | c.7142G>T p.G2381V (on ENST00000297405 / NM_001363185.1; = p.G2277V on NM_052900.3) | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52199034, COSV99820898; called by muse, mutect2, varscan2
- CSMD3 | c.2654G>A p.S885N (on ENST00000297405 / NM_001363185.1; = p.S781N on NM_052900.3) | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT tolerated (0.73); PolyPhen probably damaging (0.997); catalogued as COSV99820901; called by muse, mutect2, varscan2
- CTCF | c.139G>A p.G47R | Missense Mutation (SNP) | VAF 11/83 reads (13%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.248); catalogued as COSV50489849, COSV99864074; called by muse, mutect2, varscan2
- CTNNA2 | c.2265G>T p.M755I | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.324); catalogued as COSV100559124, COSV58149835; called by muse, mutect2, varscan2
- CYP11B1 | c.938C>G p.A313G | Missense Mutation (SNP) | VAF 31/66 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.503); catalogued as COSV52829323, COSV99454306; called by muse, mutect2, varscan2
- CYP11B1 | c.11G>A p.R4K | Missense Mutation (SNP) | VAF 123/295 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.462); catalogued as rs748062304, COSV52829032, COSV99454309; called by muse, mutect2, varscan2
- CYP4V2 | c.251A>C p.Y84S | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.521); catalogued as COSV66504842; called by muse, mutect2, varscan2
- CYP7A1 | c.571G>A p.D191N | Missense Mutation (SNP) | VAF 47/109 reads (43%) | SIFT tolerated (0.16); PolyPhen benign (0.057); catalogued as COSV100052091, COSV56965808; called by muse, mutect2, varscan2
- DBR1 | c.376A>G p.I126V | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs757813538, COSV99604333; called by muse, mutect2, varscan2
- DENND6A | c.749A>T p.Q250L | Missense Mutation (SNP) | VAF 28/59 reads (47%) | SIFT tolerated (0.06); PolyPhen benign (0.01); catalogued as COSV100231208; called by muse, mutect2, varscan2
- DUS4L-BCAP29 | c.1481C>G p.S494C | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.713); catalogued as COSV99143569; called by muse, mutect2, varscan2
- ECT2L | c.412T>C p.Y138H | Missense Mutation (SNP) | VAF 36/68 reads (53%) | SIFT deleterious (0.05); PolyPhen benign (0.049); catalogued as COSV100871716; called by muse, mutect2, varscan2
- ELOA2 | c.1558C>A p.P520T | Missense Mutation (SNP) | VAF 18/177 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs202182645, COSV55293952; called by muse, mutect2, varscan2
- ESYT2 | c.1217G>T p.G406V (on ENST00000613624; = p.G330V on NM_020728.3) | Missense Mutation (SNP) | VAF 34/105 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51754949, COSV99275867; called by muse, mutect2, varscan2
- F3 | c.566A>G p.Y189C | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100474105; called by muse, mutect2, varscan2
- FAR2 | c.400C>G p.Q134E | Missense Mutation (SNP) | VAF 109/165 reads (66%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV99478570; called by muse, mutect2, varscan2
- FASN | c.1768G>T p.A590S | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99080207; called by muse, mutect2, varscan2
- FBN1 | c.4735G>C p.A1579P | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100353790; called by muse, mutect2, varscan2
- FBXO40 | c.1727T>G p.L576R | Missense Mutation (SNP) | VAF 26/132 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100572896; called by muse, mutect2, varscan2
- FCER1G | c.65C>A p.P22H | Missense Mutation (SNP) | VAF 59/244 reads (24%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as rs538957910, COSV99248058; called by muse, mutect2, varscan2
- FCRL5 | c.53-1G>A p.X18_splice | Splice Site (SNP) | VAF 26/99 reads (26%) | catalogued as COSV100708382; called by muse, mutect2, varscan2
- FEM1C | c.1793G>A p.R598K | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99174341; called by muse, mutect2, varscan2
- FGD3 | c.977-2A>G p.X326_splice | Splice Site (SNP) | VAF 30/93 reads (32%) | catalogued as COSV100490306; called by muse, mutect2, varscan2
- FLNC | c.3559G>T p.E1187* | Nonsense Mutation (SNP) | VAF 11/55 reads (20%) | catalogued as COSV100367480, COSV57962307; called by muse, mutect2, varscan2
- FMN2 | c.5016T>A p.F1672L | Missense Mutation (SNP) | VAF 19/83 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1481812032, COSV100142027; called by muse, varscan2
- FOXP2 | c.1961G>T p.S654I | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.119); catalogued as COSV100646084; called by muse, mutect2, varscan2
- FREM2 | c.3161C>A p.T1054N | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT tolerated (0.41); PolyPhen benign (0.039); catalogued as COSV54835520, COSV99746098; called by muse, varscan2
- FSD1 | c.953del p.P318Qfs*33 | Frame Shift Del (DEL) | VAF 6/21 reads (29%) | catalogued as COSV55695669; called by mutect2, pindel, varscan2
- GAL3ST3 | c.573C>A p.Y191* | Nonsense Mutation (SNP) | VAF 26/138 reads (19%) | catalogued as rs766272801, COSV100360680; called by muse, mutect2, varscan2
- GALNT13 | c.85A>T p.S29C | Missense Mutation (SNP) | VAF 32/128 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV101221850; called by muse, mutect2, varscan2
- GCK | c.643T>A p.Y215N | Missense Mutation (SNP) | VAF 48/136 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100356965; called by muse, mutect2, varscan2
- GCNT1 | c.899T>C p.L300P | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100946379; called by muse, mutect2, varscan2
- GPHN | c.590C>T p.P197L | Missense Mutation (SNP) | VAF 94/157 reads (60%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV100014912; called by muse, mutect2, varscan2
- GRIN2A | c.4062C>G p.S1354R | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100407539; called by muse, mutect2, varscan2
- GTF3C4 | c.541C>T p.L181F | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.046); catalogued as COSV100935836; called by muse, mutect2, varscan2
- GTF3C5 | c.604G>T p.E202* | Nonsense Mutation (SNP) | VAF 18/116 reads (16%) | catalogued as COSV100565190, COSV100565434; called by muse, mutect2, varscan2
- HCN1 | c.663G>A p.W221* | Nonsense Mutation (SNP) | VAF 6/33 reads (18%) | catalogued as COSV100297783; called by muse, mutect2, varscan2
- HEMK1 | c.610C>G p.Q204E | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT tolerated (0.34); PolyPhen benign (0.014); catalogued as COSV99231512; called by muse, mutect2, varscan2
- HEPH | c.1366C>A p.L456M (on ENST00000343002; = p.L189M on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.612); catalogued as COSV100293876, COSV57964188; called by muse, mutect2, varscan2
- HHIPL2 | c.2062G>T p.A688S | Missense Mutation (SNP) | VAF 78/327 reads (24%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0); catalogued as COSV100596497; called by muse, mutect2, varscan2
- HKDC1 | c.2344G>C p.E782Q | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT tolerated (0.29); PolyPhen benign (0.174); catalogued as COSV100664307, COSV63576980; called by muse, mutect2, varscan2
- HMCN1 | c.16549C>G p.L5517V | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.012); catalogued as COSV99622490; called by muse, mutect2, varscan2
- IMPG1 | c.1192T>C p.S398P | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs765964982, COSV100885722; called by muse, mutect2, varscan2
- ITGA3 | c.1846G>T p.G616W | Missense Mutation (SNP) | VAF 22/100 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99143184; called by muse, mutect2, varscan2
- KCNN2 | c.935C>A p.T312N (on ENST00000264773; = p.T524N on NM_021614.4) | Missense Mutation (SNP) | VAF 27/68 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV99298500; called by muse, mutect2, varscan2
- KEAP1 | c.700C>T p.R234W | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV50260660; called by muse, mutect2, varscan2
- KIAA1549 | c.1930G>T p.A644S | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT tolerated (0.37); PolyPhen benign (0.015); catalogued as COSV99649396; called by mutect2, varscan2
- KLRK1 | c.65A>C p.N22T | Missense Mutation (SNP) | VAF 16/26 reads (62%) | SIFT tolerated (0.07); PolyPhen benign (0.07); catalogued as COSV99554963; called by muse, varscan2
- KMT5B | c.2405G>A p.C802Y | Missense Mutation (SNP) | VAF 37/216 reads (17%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (1); catalogued as COSV100429806; called by muse, mutect2, varscan2
- LAMA2 | c.902C>G p.A301G | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT tolerated (0.12); PolyPhen benign (0.098); catalogued as COSV101369838; called by muse, mutect2, varscan2
- LDB2 | c.860C>A p.A287D | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.776); catalogued as COSV100452333; called by muse, mutect2, varscan2
- LETM2 | c.364T>C p.Y122H (on ENST00000379957 / NM_001286819.2; = p.Y75H on NM_144652.3) | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as rs760477930, COSV99907202; called by muse, mutect2, varscan2
- LRP1B | c.6175G>C p.A2059P | Missense Mutation (SNP) | VAF 23/99 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV101249981; called by muse, mutect2, varscan2
- LRRFIP1 | c.176G>A p.R59H | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated (0.25); PolyPhen benign (0.013); catalogued as rs146354129, COSV99790246; called by muse, mutect2, varscan2
- LRTM1 | c.101T>C p.V34A | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.503); catalogued as rs745754884, COSV99835803; called by muse, mutect2, varscan2
- LTC4S | c.68C>A p.S23Y | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.726); catalogued as COSV99481979; called by muse, mutect2, varscan2
- MAP11 | c.847C>T p.H283Y | Missense Mutation (SNP) | VAF 21/143 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV100385310; called by muse, mutect2, varscan2
- MAST1 | c.1085G>T p.S362I | Missense Mutation (SNP) | VAF 12/224 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.206); catalogued as COSV99262040; called by muse, mutect2
- MED13 | c.2477-2A>G p.X826_splice | Splice Site (SNP) | VAF 7/33 reads (21%) | catalogued as COSV101180696; called by muse, mutect2, varscan2
- MMP16 | c.1373G>T p.R458I | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs1314246709, COSV99685472; called by muse, varscan2
- MOB3B | c.161A>G p.E54G | Missense Mutation (SNP) | VAF 27/87 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99218056; called by muse, mutect2, varscan2
- MSN | c.664G>T p.A222S | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.835); catalogued as COSV100814040; called by muse, mutect2, varscan2
- MYH4 | c.2717A>T p.E906V | Missense Mutation (SNP) | VAF 79/144 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99700119; called by muse, mutect2, varscan2
- MYO3B | c.1711G>A p.D571N | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.178); catalogued as rs371432418, COSV58694518; called by muse, mutect2, varscan2
- MYO7B | c.1174G>C p.A392P | Missense Mutation (SNP) | VAF 33/155 reads (21%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.702); catalogued as COSV101267806; called by muse, mutect2, varscan2
- NAV3 | c.981T>A p.S327R | Missense Mutation (SNP) | VAF 10/83 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.03); catalogued as rs1031632150, COSV99885856; called by muse, mutect2, varscan2
- NAV3 | c.2199G>T p.L733F | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99885860; called by muse, mutect2, varscan2
- NCAM2 | c.2116G>T p.G706C | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as rs748488774, COSV99520257; called by muse, varscan2
- NLRP12 | c.235C>T p.R79W | Missense Mutation (SNP) | VAF 47/151 reads (31%) | SIFT tolerated (0.05); PolyPhen benign (0.001); catalogued as rs777735292, COSV60749384; called by muse, mutect2, varscan2
- NLRP2 | c.504C>A p.F168L | Missense Mutation (SNP) | VAF 35/219 reads (16%) | SIFT tolerated (0.39); PolyPhen benign (0.184); catalogued as COSV99671728; called by muse, mutect2, varscan2
- NRG3 | c.409C>A p.P137T | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV100930338; called by muse, mutect2, varscan2
- NRXN3 | c.2759C>G p.A920G (on ENST00000335750 / NM_001330195.2; = p.A547G on NM_004796.6) | Missense Mutation (SNP) | VAF 130/195 reads (67%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.987); catalogued as COSV100199500; called by muse, mutect2, varscan2
- OBI1 | c.1236A>C p.Q412H | Missense Mutation (SNP) | VAF 33/65 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV99932175; called by muse, mutect2, varscan2
- OR10A5 | c.367C>A p.R123S | Missense Mutation (SNP) | VAF 42/184 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.895); catalogued as COSV100203346, COSV55053283, COSV55055928; called by muse, mutect2, varscan2
- OR2B11 | c.631G>A p.V211M | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.456); catalogued as rs569352082, COSV59511418; called by muse, mutect2, varscan2
- OR2M3 | c.691G>T p.G231* | Nonsense Mutation (SNP) | VAF 61/227 reads (27%) | catalogued as COSV101513386; called by muse, mutect2, varscan2
- OR2T27 | c.333G>C p.E111D | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV100788070; called by mutect2, varscan2
- OR51B5 | c.683C>G p.S228C | Missense Mutation (SNP) | VAF 22/86 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100332369, COSV56175051; called by muse, mutect2, varscan2
- OR5C1 | c.58G>A p.G20S | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.813); catalogued as COSV101030497; called by muse, mutect2, varscan2
- OR5T3 | c.584C>A p.P195H | Missense Mutation (SNP) | VAF 84/201 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100282627; called by muse, mutect2, varscan2
- OSBPL11 | c.128G>C p.S43T | Missense Mutation (SNP) | VAF 16/85 reads (19%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.099); catalogued as COSV99953883; called by muse, mutect2, varscan2
- OSBPL11 | c.127A>T p.S43C | Missense Mutation (SNP) | VAF 16/83 reads (19%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.536); catalogued as COSV99953884; called by muse, mutect2, varscan2
- OSBPL8 | c.1195G>T p.V399L | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT tolerated (0.3); PolyPhen benign (0.013); catalogued as COSV99674280; called by muse, mutect2, varscan2
- PANX2 | c.787G>T p.A263S | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.87); PolyPhen benign (0.23); catalogued as COSV99347902; called by mutect2, varscan2
- PBLD | c.310G>T p.V104F | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0.05); PolyPhen benign (0.332); catalogued as rs1194288281, COSV99515960; called by muse, mutect2, varscan2
- PCDH11X | c.3856G>T p.A1286S | Missense Mutation (SNP) | VAF 42/144 reads (29%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.005); catalogued as COSV100007095; called by muse, mutect2, varscan2
- PCDH17 | c.484G>C p.G162R | Missense Mutation (SNP) | VAF 16/31 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV100931371; called by muse, mutect2, varscan2
- PCDHB9 | c.2032C>T p.P678S | Missense Mutation (SNP) | VAF 109/470 reads (23%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.117); catalogued as COSV53378520; called by muse, mutect2, varscan2
- PCDHGA7 | c.1721G>T p.G574V | Missense Mutation (SNP) | VAF 64/157 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.403); catalogued as COSV53908569, COSV99528422; called by muse, mutect2, varscan2
- PI15 | c.649T>G p.W217G | Missense Mutation (SNP) | VAF 37/96 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99477721; called by muse, mutect2, varscan2
- PLXNA2 | c.303G>T p.Q101H | Missense Mutation (SNP) | VAF 15/95 reads (16%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.919); catalogued as COSV100884901; called by muse, mutect2, varscan2
- POLR1B | c.107A>T p.Q36L | Missense Mutation (SNP) | VAF 22/99 reads (22%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.46); catalogued as COSV99270947; called by muse, mutect2, varscan2
- POTEE | c.2645G>T p.G882V | Missense Mutation (SNP) | VAF 16/170 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs777891482, COSV58237577; called by muse, mutect2
- POU6F2 | c.1678A>T p.R560W | Missense Mutation (SNP) | VAF 40/114 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101302321; called by muse, mutect2, varscan2
- PPARGC1A | c.1051C>T p.Q351* | Nonsense Mutation (SNP) | VAF 50/117 reads (43%) | catalogued as COSV99337061; called by muse, mutect2, varscan2
- PRKCA | c.1348G>A p.G450R | Missense Mutation (SNP) | VAF 24/96 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99433330; called by muse, mutect2, varscan2
- PTGER3 | c.1139G>T p.R380M | Missense Mutation (SNP) | VAF 43/91 reads (47%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV100656080; called by muse, mutect2, varscan2
- PTPRN2 | c.1958G>T p.G653V | Missense Mutation (SNP) | VAF 43/169 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.109); catalogued as COSV67046189, COSV67060460; called by muse, mutect2, varscan2
- RANBP2 | c.6137A>G p.D2046G | Missense Mutation (SNP) | VAF 94/335 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99311018; called by muse, mutect2, varscan2
- RFC3 | c.523A>G p.I175V | Missense Mutation (SNP) | VAF 25/60 reads (42%) | SIFT tolerated (0.25); PolyPhen benign (0.122); catalogued as COSV101197783; called by muse, mutect2, varscan2
- RIN2 | c.2078C>T p.P693L (on ENST00000255006 / NM_001242581.1; = p.P644L on NM_018993.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT tolerated (0.4); PolyPhen benign (0.135); catalogued as rs747893157, COSV99656495; called by muse, varscan2
- RPAP1 | c.628G>T p.V210F | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.55); catalogued as COSV100426825; called by muse, mutect2, varscan2
- RPSA | c.601C>G p.L201V | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV100087990; called by muse, mutect2, varscan2
- RTN1 | c.958G>C p.V320L | Missense Mutation (SNP) | VAF 60/96 reads (63%) | SIFT tolerated (0.34); PolyPhen benign (0.1); catalogued as rs1407882914, COSV99954284; called by muse, mutect2, varscan2
- SEPHS2 | c.452G>T p.G151V | Missense Mutation (SNP) | VAF 14/137 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV101529296; called by muse, mutect2, varscan2
- SIGLEC10 | c.1730G>T p.R577I | Missense Mutation (SNP) | VAF 29/82 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.028); catalogued as COSV100218370; called by muse, mutect2, varscan2
- SLC27A5 | c.914C>G p.A305G | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1318685742, COSV99564075; called by muse, mutect2, varscan2
- SLC2A3 | c.893A>G p.D298G | Missense Mutation (SNP) | VAF 89/132 reads (67%) | SIFT tolerated (0.29); PolyPhen benign (0.033); catalogued as COSV99306126; called by muse, mutect2, varscan2
- SLC7A13 | c.372dup p.P125Sfs*10 | Frame Shift Ins (INS) | VAF 10/44 reads (23%) | catalogued as rs761897892; called by mutect2, varscan2
- SLC7A13 | c.48G>C p.W16C | Missense Mutation (SNP) | VAF 24/69 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs988718549, COSV99878341; called by muse, mutect2, varscan2
- SLC9A5 | c.1705A>G p.T569A | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV100236955; called by muse, mutect2, varscan2
- SLX4 | c.398C>T p.P133L | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as rs373586019; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SPATA31E1 | c.415C>A p.L139I | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV100349715; called by muse, mutect2, varscan2
- SRGAP3 | c.556A>G p.K186E | Missense Mutation (SNP) | VAF 23/82 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as COSV100840621; called by muse, mutect2, varscan2
- STXBP5 | c.284A>G p.H95R | Missense Mutation (SNP) | VAF 31/69 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99468727; called by muse, mutect2, varscan2
- SYPL1 | c.700A>C p.K234Q | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99163424; called by muse, mutect2, varscan2
- TFAP2B | c.1039C>A p.P347T | Missense Mutation (SNP) | VAF 39/91 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV99539527; called by muse, mutect2, varscan2
- TFG | c.382G>A p.E128K | Missense Mutation (SNP) | VAF 20/90 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.03); catalogued as COSV53750689; called by muse, mutect2, varscan2
- TIPARP | c.92A>G p.E31G | Missense Mutation (SNP) | VAF 23/115 reads (20%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.01); catalogued as COSV99903618; called by muse, mutect2, varscan2
- TNKS2 | c.2128A>C p.K710Q | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as COSV100860958; called by muse, mutect2, varscan2
- TNS1 | c.171G>T p.L57= | Splice Region (SNP) | VAF 5/15 reads (33%) | catalogued as COSV99409603; called by muse, mutect2, varscan2
- TRIM38 | c.821G>A p.C274Y | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0.029); catalogued as rs758632326, COSV100837517; called by muse, mutect2, varscan2
- TRIM42 | c.800A>T p.H267L | Missense Mutation (SNP) | VAF 9/80 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs778515505, COSV99647838; called by muse, mutect2, varscan2
- TRMT9B | c.232G>C p.E78Q | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs778807979, COSV101501498; called by muse, mutect2, varscan2
- TRRAP | c.5746G>C p.A1916P (on ENST00000359863 / NM_001244580.1; = p.A1898P on NM_003496.3) | Missense Mutation (SNP) | VAF 28/66 reads (42%) | SIFT tolerated (0.19); PolyPhen benign (0.017); catalogued as COSV100721734; called by muse, mutect2, varscan2
- TTN | c.31309A>G p.R10437G (on ENST00000591111; = p.R9510G on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/85 reads (20%) | PolyPhen probably damaging (0.943); catalogued as rs879070036, COSV100589308; called by muse, mutect2, varscan2
- TTN | c.15607T>A p.Y5203N (on ENST00000591111; = p.Y4276N on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/43 reads (49%) | PolyPhen probably damaging (0.998); catalogued as COSV100589310; called by muse, mutect2, varscan2
- TUBA3E | c.385T>A p.C129S | Missense Mutation (SNP) | VAF 15/88 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.06); catalogued as COSV99919590; called by muse, mutect2, varscan2
- TXLNG | c.580T>A p.L194M | Missense Mutation (SNP) | VAF 3/31 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101200538; called by muse, mutect2
- UPB1 | c.884C>A p.P295Q | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.077); catalogued as COSV58114422; called by muse, mutect2, varscan2
- VAX1 | c.183C>G p.N61K | Missense Mutation (SNP) | VAF 32/72 reads (44%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as COSV99523905; called by muse, mutect2, varscan2
- VIRMA | c.4880G>T p.G1627V | Missense Mutation (SNP) | VAF 33/77 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV99887344; called by muse, mutect2, varscan2
- WASHC4 | c.769G>C p.D257H | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.925); catalogued as COSV100161948, COSV100162478; called by muse, mutect2, varscan2
- WHRN | c.2183G>A p.R728H | Missense Mutation (SNP) | VAF 26/148 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as rs138767834; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- XYLT1 | c.545C>A p.A182E | Missense Mutation (SNP) | VAF 41/123 reads (33%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.121); catalogued as COSV99759764; called by muse, mutect2, varscan2
- YTHDC2 | c.1763A>G p.D588G | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.366); catalogued as COSV99362794; called by muse, varscan2
- ZFAT | c.1248G>C p.E416D | Missense Mutation (SNP) | VAF 23/111 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.948); catalogued as COSV100914096; called by muse, mutect2, varscan2
- ZFHX4 | c.2209C>A p.Q737K | Missense Mutation (SNP) | VAF 28/56 reads (50%) | SIFT deleterious (0.05); PolyPhen benign (0.014); catalogued as COSV99254476; called by muse, mutect2, varscan2
- ZFP42 | c.764G>T p.R255L | Missense Mutation (SNP) | VAF 27/57 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100479182, COSV58817913; called by muse, mutect2, varscan2
- ZIC1 | c.1132C>A p.R378S | Missense Mutation (SNP) | VAF 23/112 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV51557333, COSV51558618, COSV99291351; called by muse, mutect2, varscan2
- ZNF107 | c.925T>C p.F309L | Missense Mutation (SNP) | VAF 16/31 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs748034385, COSV100788158; called by muse, mutect2, varscan2
- ZNF135 | c.544C>T p.P182S (on ENST00000313434 / NM_001289401.2; = p.P194S on NM_003436.4) | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.344); catalogued as COSV100536372; called by muse, mutect2, varscan2
- ZNF157 | c.1442G>T p.R481L | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as COSV100998418; called by muse, mutect2, varscan2
- ZNF160 | c.2215G>T p.G739C | Missense Mutation (SNP) | VAF 24/97 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100762192; called by muse, mutect2, varscan2
- ZNF212 | c.1063C>T p.P355S | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.017); catalogued as rs749643786, COSV100242239; called by muse, mutect2, varscan2
- ZNF608 | c.3473C>T p.S1158F | Missense Mutation (SNP) | VAF 33/88 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.405); catalogued as rs761615973, COSV100100750; called by muse, mutect2, varscan2
- ZNF699 | c.1190G>A p.G397E | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.945); catalogued as COSV100426784, COSV58026579; called by muse, mutect2, varscan2
- CDH18 | c.861dup p.G288Wfs*7 | Frame Shift Ins (INS) | VAF 12/72 reads (17%) | called by mutect2, pindel, varscan2
- FLRT2 | c.218dup p.N73Kfs*4 | Frame Shift Ins (INS) | VAF 119/209 reads (57%) | called by mutect2, pindel, varscan2
- FRG2C | c.159G>T p.E53D | Missense Mutation (SNP) | VAF 10/212 reads (5%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.953); called by muse, mutect2
- GPR179 | c.1929G>A p.M643I (on ENST00000621958; = p.M642I on NM_001004334.4) | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- LPIN1 | c.2231del p.G744Afs*11 | Frame Shift Del (DEL) | VAF 15/59 reads (25%) | called by mutect2, pindel, varscan2
- PHF20L1 | c.523del p.V175Sfs*48 | Frame Shift Del (DEL) | VAF 15/40 reads (38%) | called by mutect2, pindel, varscan2
- SALL4 | c.442del p.D148Mfs*8 | Frame Shift Del (DEL) | VAF 105/302 reads (35%) | called by mutect2, pindel, varscan2
- THADA | c.2565_2594del p.I856_L865del | In Frame Del (DEL) | VAF 30/134 reads (22%) | called by mutect2, pindel
- TUBGCP5 | c.922-1G>A p.X308_splice | Splice Site (SNP) | VAF 7/75 reads (9%) | called by muse, mutect2
- ZDBF2 | c.2970_2972delinsAA p.R991Kfs*12 | Frame Shift Del (DEL) | VAF 22/72 reads (31%) | called by pindel, varscan2*
- ABCA6 | c.204T>C p.D68= | Silent (SNP) | VAF 11/37 reads (30%) | catalogued as COSV99445475; called by muse, varscan2
- ADGRA1 | c.1575C>T p.P525= | Silent (SNP) | VAF 14/24 reads (58%) | catalogued as COSV101192612; called by muse, mutect2, varscan2
- AMPD1 | c.687A>G p.R229= | Silent (SNP) | VAF 20/94 reads (21%) | catalogued as COSV100814782; called by muse, varscan2
- ANTXR1 | c.243C>G p.S81= | Silent (SNP) | VAF 20/87 reads (23%) | catalogued as COSV100361587; called by muse, mutect2, varscan2
- BNC1 | c.1275C>T p.D425= | Silent (SNP) | VAF 25/93 reads (27%) | catalogued as COSV100596803; called by muse, mutect2, varscan2
- CCDC120 | c.60C>T p.F20= | Silent (SNP) | VAF 20/35 reads (57%) | catalogued as rs1557079733, COSV100900540; called by muse, mutect2, varscan2
- CEACAM1 | c.1110G>A p.E370= | Silent (SNP) | VAF 11/83 reads (13%) | catalogued as COSV99362094, COSV99362276; called by muse, mutect2, varscan2
- CFAP100 | c.1503G>A p.L501= | Silent (SNP) | VAF 27/84 reads (32%) | catalogued as rs765783456, COSV100729022; called by muse, mutect2, varscan2
- CFAP44 | c.2457T>C p.V819= | Silent (SNP) | VAF 4/25 reads (16%) | catalogued as COSV99868693; called by muse, mutect2, varscan2
- CLDN25 | c.246C>A p.I82= | Silent (SNP) | VAF 44/138 reads (32%) | catalogued as COSV101493571; called by muse, mutect2, varscan2
- ESYT3 | c.588C>A p.I196= | Silent (SNP) | VAF 40/186 reads (22%) | catalogued as COSV100004706; called by muse, mutect2, varscan2
- EYS | c.225C>G p.P75= | Silent (SNP) | VAF 18/63 reads (29%) | catalogued as COSV100675477; called by muse, mutect2, varscan2
- FHOD3 | c.2568T>C p.P856= (on ENST00000359247 / NM_001281739.3; = p.P873= on NM_025135.5) | Silent (SNP) | VAF 12/37 reads (32%) | catalogued as COSV99939691; called by muse, mutect2, varscan2
- FRY | c.1947G>A p.Q649= | Silent (SNP) | VAF 23/60 reads (38%) | catalogued as COSV100968681; called by muse, mutect2, varscan2
- GOLGB1 | c.3576A>G p.K1192= | Silent (SNP) | VAF 35/164 reads (21%) | catalogued as COSV100510185; called by muse, mutect2, varscan2
- GPR139 | c.717A>T p.T239= | Silent (SNP) | VAF 8/78 reads (10%) | catalogued as COSV100429549; called by muse, mutect2, varscan2
- HEATR3 | c.1671G>T p.V557= | Silent (SNP) | VAF 5/57 reads (9%) | catalogued as COSV99589701; called by muse, mutect2
- HEXIM2 | c.312C>G p.P104= | Silent (SNP) | VAF 20/79 reads (25%) | catalogued as COSV100217820; called by muse, mutect2, varscan2
- HMCN1 | c.10674T>G p.P3558= | Silent (SNP) | VAF 16/65 reads (25%) | catalogued as COSV99622488; called by muse, mutect2, varscan2
- HOXA7 | c.147G>T p.S49= | Silent (SNP) | VAF 53/131 reads (40%) | catalogued as rs758081235, COSV99636154; called by muse, mutect2, varscan2
- IGKV1-9 | c.273A>C p.T91= | Silent (SNP) | VAF 24/153 reads (16%) | called by muse, mutect2
- IRF2BP1 | c.516T>A p.S172= | Silent (SNP) | VAF 26/82 reads (32%) | catalogued as COSV100138772; called by muse, mutect2, varscan2
- LILRB1 | c.834G>T p.L278= (on ENST00000427581; = p.L242= on NM_006669.6) | Silent (SNP) | VAF 20/95 reads (21%) | catalogued as COSV100206759; called by muse, mutect2, varscan2
- LPL | c.351T>A p.A117= | Silent (SNP) | VAF 23/79 reads (29%) | catalogued as COSV100255178; called by muse, mutect2, varscan2
- MAGEB4 | c.591G>A p.R197= | Silent (SNP) | VAF 15/26 reads (58%) | catalogued as COSV100974785; called by muse, mutect2, varscan2
- NUP107 | c.1344A>T p.T448= | Silent (SNP) | VAF 13/64 reads (20%) | catalogued as COSV99971424; called by muse, mutect2, varscan2
- OBSL1 | c.2961A>T p.P987= | Silent (SNP) | VAF 24/63 reads (38%) | catalogued as COSV99215958; called by muse, mutect2, varscan2
- OR2A14 | c.115C>T p.L39= | Silent (SNP) | VAF 25/113 reads (22%) | catalogued as rs1428401332, COSV101376437; called by muse, mutect2, varscan2
- PCDHB8 | c.1506C>A p.A502= | Silent (SNP) | VAF 129/465 reads (28%) | catalogued as rs781808480, COSV99175198; called by muse, mutect2, varscan2
- PCOLCE | c.106C>T p.L36= | Silent (SNP) | VAF 18/90 reads (20%) | catalogued as COSV99574850; called by muse, mutect2, varscan2
- PDK3 | c.492T>C p.L164= | Silent (SNP) | VAF 12/16 reads (75%) | catalogued as COSV100998081; called by muse, mutect2, varscan2
- PEG3 | c.1854G>A p.Q618= | Silent (SNP) | VAF 7/40 reads (18%) | catalogued as COSV55626202; called by muse, mutect2, varscan2
- PLK1 | c.690C>T p.F230= | Silent (SNP) | VAF 31/132 reads (23%) | catalogued as rs11645497, COSV55621900, COSV55623376; called by muse, mutect2, varscan2
- PYGM | c.2013C>T p.G671= | Silent (SNP) | VAF 37/114 reads (32%) | catalogued as rs1179145129, COSV99376593; called by muse, mutect2, varscan2
- RAVER2 | c.342A>G p.E114= | Silent (SNP) | VAF 21/40 reads (53%) | catalogued as COSV99604675; called by muse, mutect2, varscan2
- RGL4 | c.1302T>A p.A434= | Silent (SNP) | VAF 6/64 reads (9%) | catalogued as COSV99318593; called by muse, mutect2, varscan2
- SLC1A4 | c.1128C>A p.T376= | Silent (SNP) | VAF 22/92 reads (24%) | catalogued as COSV99308762, COSV99308791; called by muse, mutect2, varscan2
- SLC34A3 | c.285C>T p.S95= | Silent (SNP) | VAF 14/154 reads (9%) | catalogued as rs776608897, COSV63188502; called by muse, mutect2
- SLC6A3 | c.1275T>C p.G425= | Silent (SNP) | VAF 22/110 reads (20%) | catalogued as COSV99547713; called by muse, mutect2, varscan2
- SRGAP2 | c.3105A>T p.P1035= (on ENST00000624873 / NM_001170637.4; = p.P1036= on NM_015326.5 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 15/77 reads (19%) | called by muse, mutect2, varscan2
- TBX5 | c.1512T>C p.S504= | Silent (SNP) | VAF 10/48 reads (21%) | catalogued as COSV100090232; called by muse, mutect2, varscan2
- TCEAL3 | c.480T>A p.G160= | Silent (SNP) | VAF 13/136 reads (10%) | catalogued as COSV99685182; called by muse, mutect2, varscan2
- TCEAL6 | c.480T>A p.G160= | Silent (SNP) | VAF 31/70 reads (44%) | catalogued as COSV101035889; called by muse, mutect2, varscan2
- TMEM52B | c.216C>A p.R72= (on ENST00000381923 / NM_001079815.1; = p.R52= on NM_153022.4) | Silent (SNP) | VAF 59/93 reads (63%) | catalogued as COSV100046264; called by muse, mutect2, varscan2
- TNFRSF13B | c.99C>A p.S33= | Silent (SNP) | VAF 24/48 reads (50%) | catalogued as COSV55426818; called by muse, mutect2
- TP63 | c.1521C>T p.G507= | Silent (SNP) | VAF 20/190 reads (11%) | catalogued as COSV99285024; called by muse, mutect2
- TRBV4-2 | c.321G>A p.L107= | Silent (SNP) | VAF 18/266 reads (7%) | called by muse, mutect2
- TRIM6-TRIM34 | c.1191C>T p.N397= | Silent (SNP) | VAF 25/81 reads (31%) | catalogued as COSV100708788; called by muse, mutect2, varscan2
- TTN | c.33819C>A p.V11273= (on ENST00000591111; = p.V10346= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 8/18 reads (44%) | catalogued as COSV100589307; called by muse, varscan2
- TTN | c.21363C>A p.L7121= (on ENST00000591111; = p.L6194= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 13/76 reads (17%) | catalogued as COSV60146385; called by muse, mutect2, varscan2
- UNC45A | c.570G>A p.K190= | Silent (SNP) | VAF 19/137 reads (14%) | catalogued as COSV101265646; called by muse, mutect2, varscan2
- VHLL | c.318A>G p.T106= | Silent (SNP) | VAF 24/88 reads (27%) | catalogued as COSV100372554; called by muse, mutect2, varscan2
- WNK4 | c.1782C>T p.F594= | Silent (SNP) | VAF 33/122 reads (27%) | catalogued as rs770716517, COSV99889163; called by muse, mutect2, varscan2
- ZBTB38 | c.513C>T p.I171= | Silent (SNP) | VAF 16/143 reads (11%) | catalogued as rs371333075; called by muse, mutect2, varscan2
- ZNF2 | c.1194G>A p.T398= (on ENST00000611147 / NM_001291605.2; = p.T385= on NM_021088.4) | Silent (SNP) | VAF 11/141 reads (8%) | catalogued as rs752311758, COSV54635955; called by muse, mutect2
- SNORD115-33 | n.12G>T | RNA (SNP) | VAF 25/188 reads (13%) | called by muse, mutect2, varscan2
- SPRY4 | c.-16del | 5'UTR (DEL) | VAF 10/27 reads (37%) | called by mutect2, pindel, varscan2
- XIRP2 | c.*340C>A | 3'UTR (SNP) | VAF 13/38 reads (34%) | catalogued as COSV99736967; called by muse, mutect2, varscan2
